Gene-level copy-number profile of tumor specimen ALCH-AEJ4-TTP1-A from ALCHEMIST case ALCH-AEJ4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.0 years (27,742 days).
Specimen ALCH-AEJ4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 32f115a3-bb35-42ec-a000-b009b44d487a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEJ4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/49d917e0-7c9d-48db-916a-e67fa2438264

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 406; copy number 1: 19,416; copy number 2: 32,572; copy number 3: 5,816; copy number 4: 701; copy number 5: 1; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 195 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,432,133–47,440,691, 2 genes: FOXD2-AS1, FOXD2.
- chr1:149,700,151–149,700,296, 1 gene (within-gene range 0–1): RNU1-68P.
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–1): RNU6-904P, RPS16P3.
- chr2:201,233,443–201,287,711, 1 gene: CASP8.
- chr2:220,048,822–220,049,272, 1 gene: AC009310.1.
- chr6:958,323–1,101,400, 1 gene (within-gene range 0–1): LINC01622.
- chr6:1,079,929–1,613,897, 11 genes: AL033381.1, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:29,941,260–29,978,410, 5 genes: HLA-A, AL671277.1, HLA-W, MICD, HCG9.
- chr8:7,926,337–8,049,267, 12 genes: ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr14:18,395,626–19,936,757, 80 genes (broad region; genes not listed).
- chr18:32,245,946–32,249,032, 1 gene (within-gene range 0–2): AC015563.1.
- chr20:45,607,939–45,631,284, 2 genes (within-gene range 0–1): WFDC9, WFDC10A.
- chr21:13,038,160–15,880,069, 69 genes (broad region; genes not listed).
- chr22:46,244,011–46,263,343, 2 genes: CDPF1, PKDREJ.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene, copy number 6: AC083906.4.
- chr22:18,906,028–18,914,238, 1 gene, copy number 5 (within-gene range 3–5): DGCR6.

Autosomal genes at a single copy (total copy number 1): 17,085. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
